Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A6WP, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A6WP-01A (Primary Tumor).

100-3
Oligoastrocytoma, grade III
9382/3
Site Brain, supratentorial NOS
C71.0
JW 8/12/13

Translation
diffuse glioma with astrocytic and oligodendroglial
differentiation
IDH1 mutation
1p/19q loss
this tumor is reclassified as oligoastrocytoma
Diagnosis
anaplastic oligoastrocytoma WHO grade III

Untranslated full report is
housed at the BCR

Source: NCI Genomic Data Commons file 7a57b058-049d-4de9-919d-fb210d48897d (TCGA-S9-A6WP.55030C3A-6D25-4EB0-9B6C-FC0096472EE1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).